Gene-level copy-number profile of tumor specimen TCGA-FS-A1ZK-06A from TCGA case TCGA-FS-A1ZK, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 68.9 years (25,175 days).
Specimen TCGA-FS-A1ZK-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.6c2e7546-d2f4-4929-a0b5-b5a5752447c9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FS-A1ZK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4e611726-9f34-4f54-93df-7e26d03e3b2b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 3,415; copy number 2: 28,254; copy number 3: 16,202; copy number 4: 7,019; copy number 5: 2,645; copy number 6: 1,326; copy number 7: 472; copy number 8: 245; copy number 9: 45; copy number 10: 29; copy number 12: 149.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FS-A1ZK-06A-11D-A191-01): tumor purity 0.9, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,911 genes in 49 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–52,692,999, 761 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr4:54,009,789–55,161,880, 22 genes, copy number 7 (within-gene range 4–7): CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2.
- chr4:56,320,719–56,681,899, 14 genes, copy number 6 (within-gene range 3–6): MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1.
- chr4:62,071,752–63,143,881, 10 genes, copy number 5–7: ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1, AC074087.2, AC074087.1, HMGN1P11, EXOC5P1, AC097491.1.
- chr5:7,226,156–8,755,159, 41 genes, copy number 5: AC091889.1, Metazoa_SRP, AC091951.4, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142, ADCY2, AC093305.1, C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC116361.1, AC091941.1, AC091912.2, AC091912.1, AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2.
- chr5:86,617,928–87,499,340, 17 genes, copy number 5 (within-gene range 4–5): COX7C, SNORD138, RNU6-804P, LINC02059, AC008539.1, AC091429.1, AC109492.1, MIR4280HG, RN7SKP34, MIR4280, LINC01949, RASA1, RN7SL629P, RNU6-606P, CCNH, AC018754.1, RNU6-727P.
- chr5:91,054,834–91,799,234, 14 genes, copy number 5 (within-gene range 4–5): LUCAT1, AC074132.1, AC093281.1, AC093281.2, RNU4-90P, AC123595.1, AC123595.2, Metazoa_SRP, AC008799.1, AC008799.2, ARRDC3, ARRDC3-AS1, RAB5CP2, AC093298.2.
- chr5:95,620,087–96,631,085, 22 genes, copy number 5 (within-gene range 4–5): GPR150, RFESD, SPATA9, AC008840.1, RHOBTB3, GLRX, HSPD1P11, GGCTP1, AC008592.3, LINC01554, AC008592.4, AC008592.1, ELL2, AC104123.1, AC008592.2, FABP5P5, MIR583HG, MIR583, RNU6-524P, AC099509.1, AC099509.2, PCSK1.
- chr5:98,025,965–102,302,810, 57 genes, copy number 5–7: AC008834.1, LINC01846, AC116347.1, PSME2P1, AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1, AC114324.2, AC114324.1, GUSBP8, LINC02113, AC008837.1, AC008837.2, CRLF3P2, EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7, RNU6-1119P, AC113385.3, AC113385.2, AC113385.1, AC021086.1, FAM174A, AC027315.1, RN7SKP62, ST8SIA4, MIR548P, RN7SL802P, OR7H2P, AC117525.1, RNA5SP188, AC008948.1, SLCO4C1, RN7SKP68.
- chr5:115,578,496–116,574,823, 24 genes, copy number 5–7 (within-gene range 4–7): TICAM2, TMED7-TICAM2, AC010226.1, TMED7, AC008549.2, AC008549.1, H3P24, RNU2-49P, CDO1, ATG12, AP3S1, LINCADL, LVRN, DDX43P1, ARL14EPL, AC034236.1, AC034236.3, AC034236.2, COMMD10, RNU6-644P, HMGN2P27, AC018752.1, SEMA6A, SEMA6A-AS1.
- chr5:127,939,152–129,033,642, 7 genes, copy number 6 (within-gene range 4–6): LINC01184, SLC12A2, KDELC1P1, FBN2, Y_RNA, SLC27A6, AC008588.1.
- chr6:167,607–58,438,364, 1,527 genes, copy number 5–8 (broad region; genes not listed).
- chr7:726,699–8,262,687, 179 genes, copy number 6–12 (within-gene range 3–12) (broad region; genes not listed).
- chr7:15,611,212–19,121,916, 49 genes, copy number 6–10: MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1, HDAC9, MIR1302-6, AC010082.1, RN7SKP266, HDAC9-AS1, NPM1P13, TWIST1, AC003986.2, AC003986.3.
- chr7:44,367,140–44,848,087, 15 genes, copy number 7: AC004453.2, NUDCD3, AC004453.1, RNU6-1097P, AC004938.1, NPC1L1, DDX56, TMED4, AC004938.2, AC011894.1, OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2.
- chr8:51,810,110–55,826,445, 62 genes, copy number 5 (broad region; genes not listed).
- chr8:56,300,010–139,704,109, 1,168 genes, copy number 5–7 (broad region; genes not listed).
- chr8:140,820,599–145,066,685, 194 genes, copy number 5–6 (broad region; genes not listed).
- chr11:37,702,125–37,726,456, 2 genes, copy number 6: AC061997.1, RPL7AP56.
- chr11:55,262,155–56,703,884, 109 genes, copy number 6–12 (within-gene range 4–12) (broad region; genes not listed).
- chr11:68,941,503–70,436,584, 48 genes, copy number 6–12: AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:79,966,805–81,556,425, 11 genes, copy number 5: AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25.
- chr11:81,842,435–81,987,813, 3 genes, copy number 5: AP002802.2, MIR4300, AP002802.1.
- chr12:24,642,687–25,409,445, 21 genes, copy number 5: AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1.
- chr12:25,423,600–25,441,052, 3 genes, copy number 5: AC092451.2, FAM133GP, TUBB4BP1.
- chr12:32,985,838–33,718,217, 8 genes, copy number 5: ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1.
- chr17:28,755,978–29,294,148, 29 genes, copy number 5 (within-gene range 3–5): FAM222B, RPL31P58, Y_RNA, AC024267.2, ERAL1, AC024267.1, MIR451A, MIR451B, MIR144, MIR4732, FLOT2, AC024267.3, AC024267.6, DHRS13, PHF12, AC024267.4, AC024267.5, PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4, MYO18A, TIAF1, AC024619.3, AC005412.1, TWF1P1, CRYBA1, NUFIP2.
- chr17:51,260,546–57,685,592, 74 genes, copy number 5–7 (broad region; genes not listed).
- chr17:60,513,190–61,591,219, 27 genes, copy number 6: AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P, BCAS3, RN7SL606P, AC110602.1, Y_RNA, KRT18P61, HMGN1P28, RN7SL448P, AC005884.1, AC005884.2, RPL23AP74, AC005856.1, AC005746.3, AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1, NACA2.
- chr17:79,819,083–79,926,725, 5 genes, copy number 5: LINC01977, CBX4, AC100791.1, LINC01979, LINC01978.
- chr19:27,638,483–32,244,083, 87 genes, copy number 5 (broad region; genes not listed).
- chr19:33,080,899–35,625,355, 115 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr19:37,506,939–38,208,369, 23 genes, copy number 5–8 (within-gene range 3–8): ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1, AC011465.1, AC011479.3, AC011479.2, RN7SL663P.
- chr20:49,632,945–50,429,483, 26 genes, copy number 6: B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P.
- chr22:28,232,756–28,303,850, 2 genes, copy number 9: SNORD42, Y_RNA.
- chr22:35,501,861–35,689,373, 7 genes, copy number 5 (within-gene range 2–5): AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1.
- chr22:37,125,843–38,656,629, 71 genes, copy number 6 (broad region; genes not listed).
- chr22:40,673,484–41,446,801, 32 genes, copy number 5: GAPDHP37, MCHR1, SLC25A17, Z98048.1, JTBP1, MIR4766, ST13, XPNPEP3, DNAJB7, Metazoa_SRP, RNU6-379P, RBX1, Y_RNA, AL080243.2, Y_RNA, AL080243.1, MIR1281, EP300, RNU6-375P, AL035658.1, EP300-AS1, LRRC37A14P, L3MBTL2, L3MBTL2-AS1, CHADL, RANGAP1, MIR6889, ZC3H7B, TEF, RNU6-495P, AL008582.1, TOB2.
- chr22:49,166,421–49,266,080, 3 genes, copy number 6: Z82202.2, RPL35P8, Z82202.1.
- chr22:49,900,229–50,161,690, 11 genes, copy number 8 (within-gene range 2–8): ALG12, AL671710.1, CRELD2, BX539320.1, PIM3, MIR6821, IL17REL, TTLL8, MLC1, MOV10L1, AL034546.1.

Autosomal genes at a single copy (total copy number 1): 1,034. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
